Somatic mutation profile of tumor specimen TCGA-CN-6992-01A (aliquot TCGA-CN-6992-01A-11D-1912-08) from TCGA case TCGA-CN-6992, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.9 years (22,598 days).
Specimen TCGA-CN-6992-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6cfafab-a3eb-4b79-9a01-41507c98effe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6992-10A (Blood Derived Normal), aliquot TCGA-CN-6992-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b92839af-d972-48db-9b8e-46915f21bfc9

The open-access MAF lists 364 somatic variants for this specimen: 268 protein-altering or splice-affecting, 86 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 231, Silent 86, Nonsense Mutation 16, Frame Shift Del 7, Intron 6, Splice Site 6, Splice Region 4, RNA 4, Nonstop Mutation 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAN2B1 | c.1527+1G>C p.X509_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as rs1322313985, CS124114, COSV99666556; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; called by muse, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- A1CF | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs761190953, COSV51013818; called by muse, mutect2, varscan2
- ABCF1 | c.2183G>T p.R728L (on ENST00000326195 / NM_001025091.2; = p.R690L on NM_001090.3) | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs534029778, COSV100400641; called by muse, mutect2, varscan2
- ADAMTS1 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1337341942, COSV99535765; called by muse, mutect2, varscan2
- ADCY2 | c.3256C>A p.Q1086K | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV100601484; called by muse, mutect2, varscan2
- ADGRE1 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV51673965; called by muse, mutect2, varscan2
- ADH6 | c.450C>A p.Y150* | Nonsense Mutation (SNP) | VAF 38/99 reads (38%) | catalogued as COSV99421822; called by muse, mutect2, varscan2
- AFF2 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 75/109 reads (69%) | catalogued as COSV100648743; called by muse, mutect2, varscan2
- AKAP12 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs771936289, COSV99482224; called by mutect2, varscan2
- ANKRD30A | c.842C>A p.P281H (on ENST00000611781; = p.P225H on NM_052997.2) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); catalogued as COSV100652702; called by muse, mutect2, varscan2
- ANKS1B | c.2897G>T p.G966V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.513); catalogued as COSV100226943; called by muse, mutect2, varscan2
- ANKS1B | c.2896G>T p.G966C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.98); catalogued as COSV100226947; called by muse, mutect2, varscan2
- ANO5 | c.2658G>T p.E886D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100201294; called by muse, mutect2, varscan2
- AP4M1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs971782025, COSV57996830; called by muse, mutect2, varscan2
- APBA2 | c.2084G>T p.R695L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68788597, COSV68788915; called by muse, mutect2, varscan2
- ARMC10 | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100085578; called by muse, mutect2, varscan2
- ARMC6 | c.1173C>A p.C391* (on ENST00000392336; = p.C366* on NM_033415.4) | Nonsense Mutation (SNP) | VAF 67/202 reads (33%) | catalogued as COSV54185479, COSV99522891; called by muse, mutect2, varscan2
- ATAD2B | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750064696, COSV99476804; called by muse, mutect2, varscan2
- ATCAY | c.538C>A p.H180N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100008401; called by muse, varscan2
- ATF7 | c.887T>C p.M296T (on ENST00000548446 / NM_001366555.2; = p.M285T on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100129067; called by muse, mutect2, varscan2
- ATF7IP | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs745438627, COSV53775870; called by muse, mutect2, varscan2
- ATP10A | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs150976669; called by muse, mutect2, varscan2
- ATP13A5 | c.3323C>A p.P1108Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100664632; called by muse, mutect2, varscan2
- BFSP2 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100183465; called by muse, mutect2, varscan2
- BORA | c.1354G>A p.A452T (on ENST00000613797; = p.A377T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as rs776450111, COSV100909625; called by muse, mutect2, varscan2
- BTNL3 | c.675G>A p.E225= | Splice Region (SNP) | VAF 31/50 reads (62%) | catalogued as rs1357172042, COSV100732162; called by muse, mutect2, varscan2
- C11orf52 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99585508; called by muse, mutect2, varscan2
- C19orf44 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV99522014; called by muse, mutect2, varscan2
- C6orf118 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as COSV100023948; called by muse, mutect2, varscan2
- CACNA2D1 | c.2887G>A p.D963N (on ENST00000356253 / NM_001366867.1; = p.D951N on NM_000722.4) | Missense Mutation (SNP) | VAF 71/719 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as rs776666512, COSV62373867; called by muse, mutect2
- CANT1 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100185124; called by muse, mutect2, varscan2
- CANT1 | c.494T>A p.M165K | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM110020, COSV100185130; called by muse, mutect2, varscan2
- CCDC60 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199812180; called by muse, mutect2, varscan2
- CCNB3 | c.1772A>T p.K591M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV52081113, COSV99328335; called by muse, varscan2
- CD1C | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as rs763179021, COSV100939340; called by muse, mutect2, varscan2
- CD5L | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV100940971; called by muse, mutect2, varscan2
- CDH2 | c.1334C>G p.T445S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs200033452, COSV52297852, COSV99295291; called by muse, mutect2, varscan2
- CGA | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100851645; called by muse, mutect2, varscan2
- CHCHD6 | c.545C>G p.S182* | Nonsense Mutation (SNP) | VAF 37/50 reads (74%) | catalogued as COSV99335517; called by muse, mutect2, varscan2
- CHRM3 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs532452227, COSV55097295; called by muse, varscan2
- CILP | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV56024457, COSV56026839; called by muse, mutect2, varscan2
- CLCNKA | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100509812; called by muse, mutect2, varscan2
- CLIP2 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1554732813, COSV99790862; called by muse, mutect2, varscan2
- CLP1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs200588495, COSV100239680; called by muse, mutect2, varscan2
- CLVS2 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV99251987; called by muse, mutect2, varscan2
- COL22A1 | c.3066T>A p.C1022* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as COSV100275710; called by muse, mutect2, varscan2
- COL4A5 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086228; called by muse, mutect2, varscan2
- COL5A2 | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100879916; called by muse, mutect2, varscan2
- COL6A3 | c.9328+1G>A p.X3110_splice | Splice Site (SNP) | VAF 50/69 reads (72%) | catalogued as COSV99795922; called by muse, mutect2, varscan2
- COLGALT1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99394766, COSV99395301; called by muse, mutect2, varscan2
- COPB1 | c.1626G>C p.L542F | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99999177; called by muse, mutect2, varscan2
- COQ10B | c.527G>T p.R176I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1306590640, COSV99827251; called by muse, mutect2, varscan2
- CPXM2 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99580736; called by muse, mutect2, varscan2
- CRB1 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100957597, COSV100957610; called by muse, mutect2, varscan2
- CRTC3 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376110475; called by muse, mutect2
- CRX | c.352A>T p.K118* | Nonsense Mutation (SNP) | VAF 37/63 reads (59%) | catalogued as COSV99704322; called by muse, mutect2, varscan2
- CSMD3 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.942); catalogued as COSV52091224, COSV99821814; called by muse, mutect2, varscan2
- CYP11B1 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99454372; called by muse, mutect2, varscan2
- DAPK1 | c.1461G>A p.W487* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100800763; called by muse, mutect2, varscan2
- DENND5B | c.3590G>A p.R1197K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100170736; called by muse, mutect2, varscan2
- DHX30 | c.1432G>A p.E478K (on ENST00000445061 / NM_138615.3; = p.E439K on NM_014966.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as rs764888486, COSV99274531; called by muse, mutect2, varscan2
- DLGAP3 | c.2487C>A p.I829= | Splice Region (SNP) | VAF 66/89 reads (74%) | catalogued as COSV99332033; called by muse, mutect2, varscan2
- DMD | c.2179G>C p.D727H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs756477540, COSV55882246, COSV99918704, COSV99925621; called by muse, varscan2
- DNAH2 | c.11768G>A p.R3923H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs539312854, COSV66718058; called by mutect2, varscan2
- DNAH9 | c.7949del p.P2650Hfs*2 | Frame Shift Del (DEL) | VAF 56/179 reads (31%) | catalogued as COSV52362670; called by mutect2, pindel, varscan2
- DNM2 | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs781546006, COSV100116468; called by muse, mutect2, varscan2
- DOCK11 | c.731T>C p.M244T | Missense Mutation (SNP) | VAF 98/120 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV99352686; called by muse, mutect2, varscan2
- DOCK2 | c.5431C>T p.L1811= | Splice Region (SNP) | VAF 19/38 reads (50%) | catalogued as COSV56979142, COSV56990736; called by muse, mutect2, varscan2
- EHMT1 | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV101134978; called by muse, mutect2, varscan2
- EIF2AK3 | c.2957G>T p.G986V | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100303320; called by muse, mutect2, varscan2
- EPB41L3 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs150101312; called by muse, mutect2, varscan2
- FAM120B | c.1575C>A p.H525Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.16); catalogued as COSV99378832; called by muse, mutect2, varscan2
- FAM135B | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52714222, COSV99428250; called by muse, mutect2, varscan2
- FAM193A | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV100218437; called by muse, mutect2, varscan2
- FBXW7 | c.1574T>A p.V525E (on ENST00000281708 / NM_001349798.2; = p.V445E on NM_018315.5) | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55968758, COSV99653705; called by muse, mutect2, varscan2
- FCER1A | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100929236, COSV63668193; called by muse, mutect2, varscan2
- FCRL1 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839694; called by muse, mutect2, varscan2
- FCRL4 | c.1177A>T p.T393S | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV99619155; called by muse, mutect2, varscan2
- FMO4 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs752631143, COSV63001033; called by muse, mutect2, varscan2
- GABRP | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.089); catalogued as rs1254031279, COSV99516444; called by muse, mutect2, varscan2
- GATA3 | c.642del p.T215Pfs*50 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as COSV100651056; called by mutect2, pindel, varscan2
- GMEB2 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99823365; called by muse, mutect2, varscan2
- GPRASP2 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100176497, COSV100176971; called by muse, mutect2, varscan2
- GPRC6A | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV59955091; called by muse, mutect2, varscan2
- GREB1 | c.2697G>T p.R899S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99302033; called by muse, varscan2
- GSTA5 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52862584; called by muse, mutect2, varscan2
- GUCY2D | c.2576+1G>T p.X859_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as CS078239, COSV99643657; called by muse, mutect2, varscan2
- HCN1 | c.1119G>T p.W373C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100297949; called by muse, mutect2, varscan2
- HCN4 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99983164; called by muse, mutect2, varscan2
- HERPUD2 | c.836G>A p.W279* | Nonsense Mutation (SNP) | VAF 67/108 reads (62%) | catalogued as COSV100257769; called by muse, mutect2, varscan2
- HINFP | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640808; called by muse, mutect2, varscan2
- HMGCS2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs587712415, COSV65568203; called by muse, mutect2, varscan2
- HTR5A | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV55281358, COSV55283648; called by muse, mutect2, varscan2
- HYDIN | c.4892G>A p.R1631H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1228054176, COSV59263563; called by muse, varscan2
- ICE1 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV99663433; called by muse, mutect2, varscan2
- IGF1R | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs746040080, COSV51308679; called by muse, mutect2, varscan2
- IGFBP1 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99298613; called by muse, mutect2, varscan2
- IGHV1-3 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs782769944; called by muse, mutect2, varscan2
- IRX2 | c.528C>G p.N176K | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100121536; called by muse, mutect2, varscan2
- KCNA6 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768237; called by muse, mutect2, varscan2
- KCND1 | c.1598G>T p.C533F | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV99501639; called by muse, mutect2, varscan2
- KCNH1 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99656860; called by muse, mutect2, varscan2
- KCNS2 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99750632; called by muse, mutect2, varscan2
- KIR3DL2 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 115/215 reads (53%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.996); catalogued as COSV99551671; called by muse, mutect2, varscan2
- KIRREL3 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV101375162; called by muse, mutect2, varscan2
- KLHL4 | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100909021; called by muse, mutect2, varscan2
- KLHL5 | c.2243C>G p.A748G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.887); catalogued as COSV99784657; called by muse, mutect2, varscan2
- KNDC1 | c.3029C>G p.A1010G | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100463047; called by muse, mutect2, varscan2
- KPNA4 | c.1511G>C p.G504A | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100514926; called by muse, mutect2
- LAMC3 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1236007854, COSV100736067, COSV63093498; called by muse, mutect2, varscan2
- LCOR | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as rs896059510, COSV100603475; called by muse, mutect2, varscan2
- LGSN | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1427435720, COSV101040167; called by muse, mutect2, varscan2
- LHCGR | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1391068597, COSV54293116; called by muse, mutect2, varscan2
- LILRB2 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs371657709; called by muse, varscan2
- LIX1 | c.387C>A p.S129R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.903); catalogued as rs948995282, COSV57206131, COSV57207506; called by muse, mutect2, varscan2
- LONP2 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV99588738; called by muse, mutect2, varscan2
- LRP1B | c.10294+2T>G p.X3432_splice | Splice Site (SNP) | VAF 72/106 reads (68%) | catalogued as COSV101250634; called by muse, mutect2, varscan2
- LRP1B | c.9539C>A p.T3180K | Missense Mutation (SNP) | VAF 75/106 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101250635; called by muse, mutect2, varscan2
- MAGEC2 | c.855G>C p.E285D | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs1179252604, COSV99909342; called by muse, mutect2, varscan2
- MAGI3 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100287829, COSV56828513; called by muse, mutect2, varscan2
- MARCHF1 | c.164C>A p.A55E (on ENST00000274056; = p.A38E on NM_017923.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99919694; called by muse, mutect2, varscan2
- MC5R | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61254799; called by muse, mutect2, varscan2
- MCM7 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772794463, COSV100384498; called by muse, mutect2, varscan2
- MDC1 | c.3758C>A p.S1253Y | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100902453; called by muse, mutect2, varscan2
- MED24 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.584); catalogued as COSV100672904; called by muse, mutect2, varscan2
- MFSD2B | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs1269960409, COSV100600949, COSV57855948; called by muse, mutect2
- MMP26 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331926; called by muse, mutect2, varscan2
- MOB3C | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV99596143; called by muse, mutect2, varscan2
- MROH2B | c.1637T>C p.V546A | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV101270435; called by muse, mutect2, varscan2
- MUC16 | c.34048T>C p.W11350R | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.918); catalogued as COSV101197489; called by muse, mutect2, varscan2
- MUC17 | c.7883C>T p.P2628L | Missense Mutation (SNP) | VAF 263/374 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs146245479; called by muse, mutect2, varscan2
- MUC4 | c.14429T>A p.V4810D (on ENST00000463781 / NM_018406.7; = p.V574D on NM_004532.6) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV100203224; called by muse, mutect2, varscan2
- MYH6 | c.1315T>A p.W439R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676186; called by muse, mutect2, varscan2
- MYO16 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99193421; called by muse, mutect2, varscan2
- MYO1F | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100596294; called by muse, mutect2, varscan2
- NAA25 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 32/199 reads (16%) | catalogued as rs1287477535, COSV55709487; called by muse, mutect2, varscan2
- NAA30 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100035736; called by muse, mutect2, varscan2
- NALCN | c.2342C>A p.S781Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV51916871; called by muse, mutect2, varscan2
- NBEA | c.3869A>T p.Q1290L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.034); catalogued as COSV100076033; called by muse, mutect2
- NCOR1 | c.6930G>C p.E2310D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99246545; called by muse, mutect2, varscan2
- NDST4 | c.1976C>A p.T659K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV99995187; called by muse, mutect2, varscan2
- NDUFAF1 | c.573+1G>T p.X191_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99531284; called by muse, mutect2, varscan2
- NLRP12 | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100144708; called by muse, mutect2, varscan2
- NLRP7 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV100051451; called by muse, mutect2, varscan2
- NPAP1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); catalogued as COSV100274630; called by muse, mutect2, varscan2
- NPAP1 | c.2708C>A p.A903D | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); catalogued as COSV100274633, COSV61510505; called by muse, mutect2, varscan2
- NPFFR2 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.31); catalogued as COSV100440218; called by muse, mutect2, varscan2
- NPTXR | c.850G>C p.G284R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285308; called by muse, mutect2, varscan2
- NR1H4 | c.367C>A p.R123S (on ENST00000551379 / NM_001206993.2; = p.R113S on NM_005123.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV51849327, COSV99499901; called by muse, mutect2, varscan2
- NUP85 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.278); catalogued as rs1312108939, COSV99822843; called by mutect2, varscan2
- NYNRIN | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV66845478; called by muse, mutect2, varscan2
- OPN5 | c.824C>A p.S275* | Nonsense Mutation (SNP) | VAF 75/213 reads (35%) | catalogued as COSV99789679; called by muse, mutect2, varscan2
- OR10T2 | c.627G>C p.M209I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100554777; called by muse, mutect2, varscan2
- OR13A1 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV100980949; called by muse, mutect2, varscan2
- OR1L6 | c.859C>G p.L287V (on ENST00000373684; = p.L251V on NM_001004453.2) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100490753, COSV59028801; called by muse, mutect2, varscan2
- OR2A2 | c.355T>A p.Y119N | Missense Mutation (SNP) | VAF 101/144 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101286609; called by muse, mutect2, varscan2
- OR2M2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs775272894, COSV62897939; called by muse, mutect2, varscan2
- OR51B2 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV60916736; called by muse, mutect2, varscan2
- OR51B6 | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV100970322; called by muse, mutect2
- OR51G2 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs747962729, COSV100432016; called by muse, mutect2, varscan2
- OXCT2 | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs755094827, COSV100560260, COSV59593097; called by muse, mutect2, varscan2
- PAPPA | c.1908G>T p.M636I | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100072627; called by muse, mutect2, varscan2
- PAPPA2 | c.4748del p.G1583Efs*78 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as COSV100867408; called by mutect2, pindel, varscan2
- PASK | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV52152154; called by muse, varscan2
- PC | c.1978T>A p.F660I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.352); catalogued as COSV101211867; called by muse, mutect2, varscan2
- PCDH10 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 114/177 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV99992740; called by muse, mutect2, varscan2
- PCDHGB3 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as rs532361069, COSV104390587, COSV99528841; called by muse, mutect2, varscan2
- PHF3 | c.2414T>G p.L805R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV100012784; called by muse, mutect2, varscan2
- PIWIL2 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100769150; called by muse, mutect2, varscan2
- PKHD1 | c.8185G>A p.A2729T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100580776; called by muse, mutect2, varscan2
- PLEC | c.11707C>T p.R3903W (on ENST00000322810 / NM_201380.4; = p.R3793W on NM_000445.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1261148089, COSV59695710; called by muse, mutect2, varscan2
- PLEC | c.8246C>G p.S2749* (on ENST00000322810 / NM_201380.4; = p.S2639* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100509446; called by muse, mutect2
- POT1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100713958; called by muse, mutect2, varscan2
- PPEF1 | c.1477C>A p.Q493K | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs745674082, COSV100583484; called by muse, mutect2, varscan2
- PRKCG | c.1108C>G p.R370G | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV99668390; called by muse, mutect2, varscan2
- PRKCQ | c.1199A>T p.K400M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV99576145; called by muse, mutect2, varscan2
- PRPF40B | c.1874G>A p.R625K (on ENST00000380281; = p.R612K on NM_012272.3) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99525483; called by muse, mutect2, varscan2
- PRRC2A | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.532); catalogued as COSV101050972; called by muse, mutect2, varscan2
- PTPN13 | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.524); catalogued as COSV100363871; called by muse, mutect2, varscan2
- PTPRR | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.076); catalogued as COSV99315870; called by muse, mutect2, varscan2
- PURG | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99988130; called by muse, mutect2, varscan2
- RAG1 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100200597; called by muse, mutect2, varscan2
- RALGPS2 | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100860593; called by muse, mutect2, varscan2
- RBMX2 | c.570A>T p.R190S | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV100564700; called by muse, mutect2, varscan2
- RGR | c.668C>A p.T223K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100812813; called by muse, mutect2, varscan2
- RHOXF2B | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs782210640, COSV65054813; called by muse, mutect2, varscan2
- RLF | c.4774G>A p.V1592I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs772598854, COSV65652383; called by muse, mutect2, varscan2
- RNF113B | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57434143; called by muse, mutect2, varscan2
- ROBO2 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100163572; called by muse, mutect2, varscan2
- RXRG | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100717149; called by muse, mutect2, varscan2
- SACS | c.8707G>T p.V2903F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV101207130; called by muse, mutect2, varscan2
- SCN1A | c.2094C>A p.H698Q (on ENST00000303395 / NM_001202435.3; = p.H687Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV100318905; called by muse, mutect2, varscan2
- SCN4A | c.3958T>A p.Y1320N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101438284; called by muse, mutect2, varscan2
- SCN8A | c.319A>G p.S107G | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100633058; called by muse, mutect2, varscan2
- SELP | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553948727, COSV99738801; called by muse, mutect2, varscan2
- SEPTIN14 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101193162; called by muse, mutect2, varscan2
- SETBP1 | c.2602G>T p.D868Y | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM103046, COSV56311800, COSV56326819; called by muse, mutect2, varscan2
- SF3B6 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99272538; called by muse, mutect2
- SHPRH | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.73); catalogued as COSV99261087; called by muse, mutect2, varscan2
- SLC18A3 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs149097990; called by muse, mutect2, varscan2
- SLC22A25 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as COSV100123375; called by muse, mutect2, varscan2
- SLC25A16 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370997821; called by muse, mutect2, varscan2
- SLC25A51 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV99643239; called by muse, mutect2, varscan2
- SLC52A2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.37); catalogued as rs781928955, COSV57352133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A12 | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 152/387 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV99744262; called by muse, mutect2, varscan2
- SLC9A8 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100846217; called by muse, mutect2, varscan2
- SMARCA2 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100570134, COSV100571303; called by muse, mutect2, varscan2
- SNAP91 | c.1891G>C p.A631P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); catalogued as COSV99534056; called by muse, mutect2
- SNRNP200 | c.5340C>G p.H1780Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV100106965; called by muse, mutect2, varscan2
- SNTB1 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101179658; called by muse, mutect2, varscan2
- SNURF | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100577800; called by muse, mutect2, varscan2
- SPAG16 | c.1895G>C p.*632Sext*15 | Nonstop Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100435084; called by muse, mutect2
- SPAG17 | c.5144G>T p.R1715L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs748999990, COSV100307559; called by muse, mutect2, varscan2
- SPANXN3 | c.79-1G>T p.X27_splice | Splice Site (SNP) | VAF 46/62 reads (74%) | catalogued as COSV100980835, COSV65140521, COSV65140574; called by muse, mutect2, varscan2
- SPATA31D1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as rs1387527818, COSV100782403; called by muse, mutect2, varscan2
- SYCP1 | c.2740T>A p.Y914N | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV101050709; called by muse, mutect2, varscan2
- TBC1D9B | c.2790A>T p.P930= | Splice Region (SNP) | VAF 6/14 reads (43%) | catalogued as COSV62282301; called by muse, mutect2, varscan2
- TCF12 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV51011834; called by muse, mutect2, varscan2
- TGM4 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99942097; called by muse, mutect2, varscan2
- TGM4 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99942099, COSV99942398; called by muse, mutect2, varscan2
- THADA | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100367711; called by muse, mutect2, varscan2
- THOC2 | c.3920G>A p.R1307Q | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99053750, COSV99832590; called by muse, mutect2
- TIAM1 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99732110; called by muse, mutect2, varscan2
- TKT | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs148472107; called by muse, mutect2, varscan2
- TM9SF4 | c.1744G>C p.V582L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.592); catalogued as COSV99453729; called by muse, mutect2, varscan2
- TMEM26 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as COSV101051659; called by muse, mutect2, varscan2
- TNIK | c.2432T>C p.L811P | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99454389; called by muse, mutect2, varscan2
- TOP1MT | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100239113; called by muse, mutect2, varscan2
- TPGS2 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs755462731, COSV100528697; called by muse, mutect2, varscan2
- TPH1 | c.163A>G p.R55G | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100000574; called by muse, mutect2, varscan2
- TPX2 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as COSV100301448; called by muse, mutect2
- TRIML2 | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58718445; called by muse, mutect2, varscan2
- TRPV4 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99924302; called by muse, mutect2, varscan2
- TTC17 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV99234531; called by muse, mutect2, varscan2
- TTN | c.37975G>A p.V12659M (on ENST00000591111; = p.V5235M on NM_003319.4) | Missense Mutation (SNP) | VAF 57/81 reads (70%) | PolyPhen benign (0.007); catalogued as COSV100590544; called by muse, mutect2, varscan2
- TWF2 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1361922183, COSV100564413; called by muse, mutect2, varscan2
- UNC13C | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as rs1439183824, COSV99510308; called by muse, mutect2, varscan2
- USP34 | c.2513A>G p.H838R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV101276542; called by muse, mutect2, varscan2
- WASHC2A | c.1586C>A p.S529* | Nonsense Mutation (SNP) | VAF 53/280 reads (19%) | catalogued as COSV99254760; called by muse, varscan2
- WDFY3 | c.6422T>A p.I2141N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV99881572; called by muse, mutect2, varscan2
- WNK1 | c.3182C>T p.P1061L (on ENST00000315939 / NM_018979.4; = p.P814L on NM_014823.3) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs756270744, COSV60036411; called by muse, mutect2, varscan2
- XIRP2 | c.9178C>T p.P3060S (on ENST00000628543; = p.P3235S on NM_152381.6) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as COSV99737339; called by muse, mutect2, varscan2
- ZBED2 | c.160T>A p.F54I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99342184; called by muse, mutect2, varscan2
- ZBTB20 | c.1550C>T p.A517V (on ENST00000474710 / NM_001164342.2; = p.A444V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.939); catalogued as rs771120579, COSV61863801; called by muse, mutect2, varscan2
- ZFP14 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV99524940; called by muse, mutect2, varscan2
- ZNF236 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.837); catalogued as rs776798483, COSV53487107; called by muse, mutect2, varscan2
- ZNF260 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1484055815, COSV101591028; called by muse, mutect2, varscan2
- ZNF426 | c.1401G>T p.M467I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99464895; called by muse, mutect2, varscan2
- ZNF479 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV100482385; called by muse, mutect2, varscan2
- ZNF560 | c.1998T>A p.S666R | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV100038167; called by muse, mutect2, varscan2
- ZNF624 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100256938; called by muse, mutect2, varscan2
- ZNF646 | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100336262; called by muse, mutect2
- ZNF676 | c.510G>C p.E170D (on ENST00000650058; = p.E138D on NM_001001411.3) | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV101236076; called by muse, mutect2
- ZNF804A | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 70/93 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV100165920; called by muse, mutect2, varscan2
- ZP3 | c.385G>A p.V129M (on ENST00000394857 / NM_001110354.2; = p.V78M on NM_007155.6) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as rs144669807; called by muse, mutect2, varscan2
- ZZEF1 | c.4873G>A p.D1625N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV101067398; called by muse, mutect2, varscan2
- ABCA1 | c.6595_6612del p.K2199_E2204del | In Frame Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- COL4A3 | c.4472del p.G1491Afs*38 | Frame Shift Del (DEL) | VAF 63/107 reads (59%) | called by mutect2, pindel, varscan2
- E2F8 | c.501_505del p.L167Ffs*33 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- EMC4 | c.536_*9del | Nonstop Mutation (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel
- IGLV4-69 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCAN | c.3276del p.W1092Cfs*32 | Frame Shift Del (DEL) | VAF 38/115 reads (33%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1316T>A p.L439Q | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PGBD1 | c.2090del p.L697Rfs*8 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.6064dup p.R2022Kfs*8 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- ABCC9 | c.1194C>A p.L398= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99684120; called by muse, mutect2, varscan2
- ADGRG4 | c.3573C>T p.F1191= | Silent (SNP) | VAF 76/103 reads (74%) | catalogued as COSV99794122; called by muse, mutect2, varscan2
- AGO2 | c.1338C>T p.I446= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as rs142051728; called by muse, mutect2, varscan2
- ATP2B4 | c.3429A>G p.P1143= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100396946; called by muse, mutect2, varscan2
- CACNA1E | c.3225C>T p.P1075= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs572301954, COSV100701198, COSV100705626; called by muse, mutect2
- CACNB2 | c.844C>A p.R282= (on ENST00000324631 / NM_201596.3; = p.R227= on NM_000724.4) | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as rs1302655499, COSV99992569; called by muse, mutect2, varscan2
- CADM1 | c.1167G>C p.L389= | Silent (SNP) | VAF 56/103 reads (54%) | catalogued as COSV100522022; called by muse, mutect2, varscan2
- CCN4 | c.84C>A p.A28= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99136925; called by muse, varscan2
- CHD7 | c.7470G>A p.S2490= | Silent (SNP) | VAF 33/208 reads (16%) | catalogued as rs780608336, COSV101418378, COSV71111008; called by muse, mutect2, varscan2
- CPSF1 | c.594G>A p.E198= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100574128; called by muse, mutect2, varscan2
- CSMD3 | c.759C>A p.S253= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99821813; called by muse, mutect2, varscan2
- DAAM2 | c.2916G>T p.R972= (on ENST00000274867 / NM_001201427.2; = p.R971= on NM_015345.3) | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV51342448, COSV51421437, COSV99224280; called by muse, mutect2, varscan2
- DCAF4L1 | c.210G>T p.A70= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100295489; called by muse, mutect2, varscan2
- DCHS1 | c.1575C>A p.P525= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100201349; called by muse, mutect2, varscan2
- DOT1L | c.2001C>T p.D667= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs776501955, COSV67112272; called by muse, mutect2, varscan2
- DPPA5 | c.120C>T p.D40= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100951476; called by muse, mutect2, varscan2
- FBXO7 | c.1221G>A p.P407= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs201127594, COSV56677181; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXP2 | c.993G>C p.S331= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100646128, COSV63488109; called by muse, mutect2
- FTHL17 | c.78G>C p.T26= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs760292130, COSV100784228, COSV63266610; called by muse, mutect2, varscan2
- FUNDC2 | c.210C>T p.F70= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs147164809, COSV65670987; called by muse, mutect2, varscan2
- GART | c.2559G>A p.A853= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs763016241, COSV101111318; called by muse, mutect2, varscan2
- GCNT2 | c.36G>A p.A12= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as rs142352495; called by muse, mutect2, varscan2
- GET3 | c.81A>C p.T27= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99662147; called by muse, mutect2, varscan2
- GLI2 | c.1548T>C p.Y516= (on ENST00000361492 / NM_001374353.1; = p.Y533= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100082126; called by muse, mutect2, varscan2
- GLRA4 | c.129C>A p.S43= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV101009531; called by muse, mutect2, varscan2
- GRIP1 | c.1788A>T p.P596= (on ENST00000359742 / NM_001379345.1; = p.P544= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as COSV99667638; called by muse, mutect2, varscan2
- GYS1 | c.1389C>A p.I463= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV99620297; called by muse, mutect2, varscan2
- HCN1 | c.2139C>G p.A713= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100297947, COSV100301522, COSV57531008; called by muse, mutect2, varscan2
- HCN1 | c.315G>T p.G105= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100297951, COSV57504675; called by muse, mutect2, varscan2
- HSD17B1 | c.402T>C p.G134= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99864584; called by muse, mutect2, varscan2
- IGKV1-9 | c.270G>T p.G90= | Silent (SNP) | VAF 98/358 reads (27%) | called by muse, mutect2, varscan2
- IKBKB | c.783C>T p.Y261= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as rs150493359; called by muse, mutect2, varscan2
- INSYN1 | c.225G>A p.T75= | Silent (SNP) | VAF 100/257 reads (39%) | catalogued as rs559180260, COSV101138673; called by muse, mutect2, varscan2
- IPO5 | c.570G>A p.R190= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs760432194, COSV99846904; called by muse, mutect2, varscan2
- IQCN | c.3357C>T p.A1119= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100828153; called by muse, mutect2, varscan2
- ITGAM | c.1362C>T p.G454= | Silent (SNP) | VAF 32/224 reads (14%) | catalogued as rs369936883; called by muse, mutect2, varscan2
- KLHDC7B | c.1065C>T p.Y355= (on ENST00000395676; = p.Y996= on NM_138433.5) | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV101192879; called by muse, mutect2, varscan2
- LDHD | c.1314C>G p.A438= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs768095187, COSV100096551; called by muse, mutect2, varscan2
- LRIF1 | c.2295G>A p.K765= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100870779; called by muse, mutect2, varscan2
- MARCHF6 | c.1350C>T p.V450= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV99929264; called by muse, mutect2, varscan2
- MCM10 | c.927G>T p.V309= (on ENST00000484800 / NM_182751.3; = p.V308= on NM_018518.5) | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV101097857; called by muse, mutect2, varscan2
- MCM2 | c.2199G>A p.P733= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs144817363; called by muse, mutect2, varscan2
- MDC1 | c.4641C>G p.V1547= | Silent (SNP) | VAF 52/276 reads (19%) | catalogued as COSV100902451; called by muse, mutect2, varscan2
- MGAT1 | c.1305G>T p.L435= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100286486; called by muse, mutect2, varscan2
- MME | c.1857C>A p.S619= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV100852154, COSV64710280; called by muse, mutect2, varscan2
- MUC16 | c.41905C>T p.L13969= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101109509; called by muse, mutect2
- NCOA3 | c.4239T>C p.S1413= (on ENST00000371998 / NM_181659.3; = p.S1409= on NM_006534.4) | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV100506996; called by muse, mutect2, varscan2
- NDN | c.747C>T p.R249= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV59361679; called by muse, mutect2, varscan2
- NKX6-2 | c.471C>A p.G157= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100888309; called by muse, mutect2, varscan2
- NRXN3 | c.252C>T p.G84= (on ENST00000557594 / NM_001272020.2; = p.G716= on NM_004796.6) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1012851739, COSV55348718; called by muse, mutect2, varscan2
- OLFM4 | c.885A>T p.T295= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV99524151; called by muse, mutect2, varscan2
- OLIG3 | c.321C>T p.R107= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1487922443, COSV62988597; called by muse, mutect2, varscan2
- OR4C16 | c.570C>A p.T190= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100113770, COSV58942112; called by muse, mutect2, varscan2
- OR5A2 | c.822G>T p.V274= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV100119639; called by muse, mutect2, varscan2
- PCDHB7 | c.1470G>C p.L490= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV99175254; called by muse, mutect2, varscan2
- PDLIM1 | c.87C>T p.A29= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs775650719, COSV100267604; called by muse, mutect2, varscan2
- PLEKHG1 | c.288C>T p.N96= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs141401834; called by muse, mutect2, varscan2
- POU4F2 | c.759C>A p.A253= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV99850212; called by mutect2, varscan2
- PRPF40B | c.1785G>A p.L595= (on ENST00000380281; = p.L582= on NM_012272.3) | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV99525481; called by muse, mutect2, varscan2
- PTCHD4 | c.351C>T p.L117= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs745310753, COSV100259689; called by muse, mutect2, varscan2
- PXN | c.1695C>G p.L565= (on ENST00000228307 / NM_001080855.3; = p.L531= on NM_002859.4) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99935577; called by muse, mutect2
- RIPOR1 | c.657C>T p.F219= (on ENST00000379312 / NM_001193522.2; = p.F215= on NM_024519.4) | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs747087160, COSV50219932; called by muse, mutect2, varscan2
- RSF1 | c.1140C>T p.A380= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV100406800; called by muse, mutect2, varscan2
- RTL9 | c.1494C>T p.S498= | Silent (SNP) | VAF 103/137 reads (75%) | catalogued as COSV101511606; called by muse, mutect2, varscan2
- RXFP1 | c.1476C>A p.A492= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV100313484; called by muse, mutect2, varscan2
- SACM1L | c.1149C>T p.G383= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs138504596; called by muse, mutect2, varscan2
- SERPINB6 | c.873G>T p.P291= (on ENST00000612421 / NM_001271823.2; = p.P272= on NM_004568.6) | Silent (SNP) | VAF 86/253 reads (34%) | catalogued as COSV100177368; called by muse, mutect2, varscan2
- SFMBT2 | c.1683G>C p.V561= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV100738289; called by muse, mutect2, varscan2
- SFT2D2 | c.69T>C p.V23= | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as COSV99607845; called by muse, mutect2, varscan2
- SHPRH | c.879G>A p.V293= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as COSV99261093; called by muse, mutect2, varscan2
- SIPA1L2 | c.3492C>T p.D1164= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs764682648, COSV99476942; called by mutect2, varscan2
- SLC38A6 | c.1344C>G p.L448= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99959346; called by muse, mutect2, varscan2
- SLC9A8 | c.1026C>A p.V342= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV100846216; called by muse, mutect2, varscan2
- SLITRK3 | c.2074C>A p.R692= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV104384557, COSV53848544, COSV99578223; called by muse, mutect2, varscan2
- SPHKAP | c.219A>T p.V73= | Silent (SNP) | VAF 74/114 reads (65%) | catalogued as COSV100763608; called by muse, mutect2, varscan2
- SPTBN5 | c.4053A>T p.T1351= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100310475; called by muse, mutect2, varscan2
- ST18 | c.903G>A p.G301= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV52514982; called by muse, mutect2, varscan2
- STRC | c.453G>T p.G151= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV70833133, COSV70835970; called by mutect2, varscan2
- TBC1D4 | c.540G>A p.A180= | Silent (SNP) | VAF 75/243 reads (31%) | catalogued as rs373080119, COSV66490277; called by muse, mutect2, varscan2
- TECTA | c.831G>A p.L277= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV99878272; called by muse, mutect2, varscan2
- TLE6 | c.1485C>T p.H495= (on ENST00000246112 / NM_001143986.2; = p.H372= on NM_024760.3) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs747046146, COSV99503966; called by muse, mutect2, varscan2
- TMEM215 | c.72T>A p.G24= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV100713126; called by muse, mutect2, varscan2
- TNK1 | c.1359A>G p.P453= (on ENST00000576812 / NM_001251902.2; = p.P448= on NM_003985.5) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100247781; called by muse, mutect2, varscan2
- ZNF131 | c.411A>T p.T137= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100185072; called by muse, mutect2, varscan2
- ZNF274 | c.414G>A p.L138= (on ENST00000610905; = p.L33= on NM_016324.3) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1292473926, COSV100464624, COSV100465149; called by mutect2, varscan2
- ZNF366 | c.1065C>T p.H355= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs539424512, COSV100574009; called by muse, mutect2, varscan2
- CCNQP1 | n.316C>A | RNA (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14841G>T | Intron (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100227453; called by mutect2, varscan2
- HNRNPU | c.634+950G>C | Intron (SNP) | VAF 48/132 reads (36%) | catalogued as COSV99309773; called by muse, mutect2, varscan2
- MIR541 | n.25C>T | RNA (SNP) | VAF 25/46 reads (54%) | catalogued as rs772118104; called by muse, mutect2, varscan2
- MIR543 | n.56C>T | RNA (SNP) | VAF 22/41 reads (54%) | catalogued as rs760890689; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109836G>T | Intron (SNP) | VAF 23/38 reads (61%) | catalogued as rs747566761, COSV100452726; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2W5 | n.1002C>A | RNA (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- RPL7A | c.415+62C>G | Intron (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100034522, COSV100034871; called by muse, mutect2, varscan2
- RPS6KA2 | c.908-5896A>G | Intron (SNP) | VAF 32/97 reads (33%) | catalogued as COSV99689992; called by muse, mutect2, varscan2
- SON | c.6657+178G>A | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as rs1048755805, COSV99276546; called by muse, mutect2, varscan2
